Gene-level copy-number profile of tumor specimen TCGA-CN-6024-01A from TCGA case TCGA-CN-6024, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 66.4 years (24,259 days).
Specimen TCGA-CN-6024-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.b24695ff-10a8-480f-885a-3da3356b3678.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CN-6024-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3342ffff-3ae0-43b8-b3cf-17b66153a9d4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 750; copy number 2: 24,130; copy number 3: 21,615; copy number 4: 8,563; copy number 5: 1,497; copy number 6: 646; copy number 7: 886; copy number 8: 1,014; copy number 9: 101; copy number 10: 159; copy number 11: 235; copy number 12: 81; copy number 16: 132.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CN-6024-01A-11D-1682-01): tumor purity 0.61, ploidy 2.99, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4,751 genes in 25 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:204,828,651–248,919,946, 980 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr2:105,600,703–106,698,676, 23 genes, copy number 6: AC018802.1, AC018802.2, NCK2, AC010978.1, AC009505.1, ECRG4, UXS1, AC018878.1, AC092106.1, RPL22P10, SRSF3P4, RPS21P2, RPL27AP4, ILRUNP1, AC114755.1, ANAPC1P6, PLGLA, RGPD3, AC097527.1, CD8B2, AC108868.2, AC108868.1, EEF1A1P12.
- chr2:106,822,923–106,825,031, 1 gene, copy number 6: ST6GAL2-IT1.
- chr2:123,421,486–124,025,173, 7 genes, copy number 5: AC073409.2, AC073409.1, ELOAP1, PSMD14P1, AC064859.1, RN7SKP102, AC079154.1.
- chr2:157,257,705–158,136,154, 15 genes, copy number 7 (within-gene range 3–7): GALNT5, RN7SKP281, ERMN, FAM133DP, CYTIP, ACVR1C, AC019186.1, ACVR1, UPP2, AC013731.1, RNU6-436P, AC091488.1, MTA3P1, RNU6-932P, PTP4A1P1.
- chr2:184,049,467–185,833,290, 12 genes, copy number 5: AC096555.1, AC020584.1, MIR548AE1, AC096667.1, ZNF804A, RPL23AP33, AC009315.1, ELF2P4, FSIP2-AS1, U8, FSIP2-AS2, FSIP2.
- chr3:93,843,764–96,619,831, 24 genes, copy number 6–10: RNU6-488P, PROS1, Y_RNA, RNU6-511P, ARL13B, HMGN1P7, STX19, DHFR2, NSUN3, RBBP4P2, ARMC10P1, AC140059.1, WDR82P1, LINC00879, RPS18P6, MTHFD2P1, AC106719.1, AC107304.1, HNRNPKP4, MIR8060, AC107015.1, RNU6-1094P, MTRNR2L12, RPL18AP8.
- chr3:97,481,177–98,088,102, 12 genes, copy number 5: AC117470.1, AC110491.1, ARL6, AC110491.3, CRYBG3, AC110491.2, RIOX2, AC026100.1, GABRR3, OR5BM1P, OR5AC1, OR5AC2.
- chr3:98,100,793–98,105,672, 1 gene, copy number 5: OR5AC4P.
- chr8:46,028,804–145,066,685, 1,534 genes, copy number 6–11 (broad region; genes not listed).
- chr9:22,446,824–23,438,700, 6 genes, copy number 6–9: DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL357614.1.
- chr9:26,840,685–27,297,150, 13 genes, copy number 6: CAAP1, H3P31, RN7SL100P, PLAA, IFT74, IFT74-AS1, LRRC19, AL355432.1, TEK, RNA5SP280, AL355433.1, LINC00032, EQTN.
- chr9:32,293,558–43,045,120, 376 genes, copy number 6 (broad region; genes not listed).
- chr11:89,177,875–90,915,052, 66 genes, copy number 7–11 (within-gene range 4–11) (broad region; genes not listed).
- chr12:66,767–34,249,958, 850 genes, copy number 8–16 (broad region; genes not listed).
- chr17:13,494,032–17,423,704, 140 genes, copy number 11–12 (broad region; genes not listed).
- chr18:47,390–6,415,237, 126 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr18:21,981,121–24,162,211, 44 genes, copy number 11 (within-gene range 4–11): LINC01900, AC091043.1, RNU6ATAC20P, GATA6-AS1, GATA6, AC091588.1, RNU6-702P, AC091588.3, AC091588.2, AC027449.1, CTAGE1, ATP7BP1, RPS4XP18, RNU6-1032P, AC090912.1, AC090912.2, RBBP8, AC090912.3, UBE2CP2, MIR4741, RN7SL745P, Y_RNA, CABLES1, TMEM241, AC011731.1, RIOK3, Y_RNA, AC026634.1, RMC1, NPC1, Y_RNA, ANKRD29, RPS10P27, LAMA3, RPL23AP77, AC010754.1, TTC39C, TTC39C-AS1, AC090772.2, AC090772.1, RNU5A-6P, AC090772.4, CABYR, AC090772.3.
- chr18:24,170,505–24,218,404, 3 genes, copy number 11: RNA5SP452, Metazoa_SRP, RNU6-435P.
- chr18:25,061,924–29,257,060, 48 genes, copy number 7–12 (within-gene range 4–12): ZNF521, AC105114.2, AC105114.1, AC110603.1, RN7SL97P, AC027229.1, SS18, RPS24P18, PSMA8, DHFRP1, NPM1P2, TAF4B, SINHCAFP1, AC121320.1, AC022069.1, RNU6-1289P, LINC01543, KCTD1, AC007996.1, AC090206.1, MIR8057, CIAPIN1P, AQP4-AS1, AC012588.1, PCAT18, U3, AC018371.1, AC018371.2, AQP4, CHST9, ATP6V1E1P2, LINC01908, AC090403.1, AC021382.1, UBA52P9, AC068408.1, RBM22P1, PA2G4P3, AC068408.2, AC090936.1, CDH2, AC110015.1, AC006249.1, AC090365.1, ARIH2P1, AC023932.1, RNU6-408P, AC105245.1.
- chr20:20,389,530–33,443,763, 273 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr20:35,172,072–35,216,240, 1 gene, copy number 6 (within-gene range 3–6): PROCR.
- chr20:35,195,306–35,950,370, 37 genes, copy number 6 (within-gene range 3–6): RNA5SP483, MMP24OS, MT1P3, MMP24, AL121753.2, AL121753.1, EIF6, FAM83C-AS1, FAM83C, UQCC1, GDF5-AS1, GDF5, MIR1289-1, CEP250, CEP250-AS1, FO393401.1, C20orf173, ERGIC3, RPL36P4, FER1L4, RPL37P1, SPAG4, CPNE1, AL109827.1, RN7SKP271, RNU6-759P, RBM12, NFS1, ROMO1, RBM39, RPF2P1, U6, PHF20, COX7BP2, Y_RNA, HIGD1AP16, RNU4-40P.
- chr21:10,328,411–20,598,163, 146 genes, copy number 5–10 (broad region; genes not listed).
- chr21:22,098,616–23,131,206, 13 genes, copy number 12: LINC00308, AP000705.2, AP000705.1, RNU4-45P, AP000561.1, MAPK6P2, AP000959.1, AP000949.1, AP001116.1, MIR6130, ZNF299P, MSANTD2P1, AP001255.1.

Autosomal genes at a single copy (total copy number 1): 749. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
